Gene-level copy-number profile of tumor specimen C3N-00306-02 from CPTAC case C3N-00306, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 50.8 years (18,561 days).
Specimen C3N-00306-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 337dce26-6e24-4279-a689-818432b95e8d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00306-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/6717e3cd-4faa-4594-9a15-2bb8c27c8cc9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 526; copy number 1: 5,909; copy number 2: 41,047; copy number 3: 8,489; copy number 4: 2,802; copy number 5: 122; copy number 8: 5; copy number 9: 3.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,234,256–11,557,665, 5 genes (within-gene range 0–1): CHCHD4P4, ATG7, AC083855.1, AC026185.1, AC022001.1.
- chr9:64,462,819–64,498,745, 6 genes: CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1.
- chr9:64,817,870–64,836,341, 1 gene: AL359955.1.
- chr9:65,282,101–65,285,209, 1 gene: FOXD4L5.
- chr20:63,127,495–63,129,459, 1 gene: AL096828.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 130 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:111,726,110–121,441,261, 121 genes, copy number 5–9 (broad region; genes not listed).
- chr9:64,621,560–64,765,535, 5 genes, copy number 8: AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.
- chr9:65,287,914–65,734,041, 4 genes, copy number 5: CBWD4P, Y_RNA, FRG1KP, CBWD5.

Autosomal genes at a single copy (total copy number 1): 4,604. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
